Somatic mutation profile of tumor specimen TARGET-20-PATAUU-04A (aliquot TARGET-20-PATAUU-04A-01D) from TARGET case TARGET-20-PATAUU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,295 days).
Specimen TARGET-20-PATAUU-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1811d1f7-16b6-4fca-a121-19485dc94471.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATAUU-14A (Bone Marrow Normal), aliquot TARGET-20-PATAUU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e022ac94-a509-4913-8a11-88380315b123

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 32/161 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATF7IP | c.3740A>G p.D1247G | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53775026; called by muse, mutect2, varscan2
- ASXL2 | c.2751_2752insTG p.S918* | Frame Shift Ins (INS) | VAF 47/266 reads (18%) | called by mutect2, pindel, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- GATA2 | c.591C>T p.S197= | Silent (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
